Somatic mutation profile of tumor specimen BA2728D (aliquot aq-BA2728D) from BEATAML1.0 case 2094, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia with inv(3)(q21q26.2) or t(3;3)(q21;q26.2), RPN1-EVI1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 58.4 years (21,315 days).
Specimen BA2728D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d5502aac-27d1-4897-85b4-6ad54c02646c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2678D (Solid Tissue Normal), aliquot aq-BA2678D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a9c0fbc5-4bb7-400f-8207-a8570439b664

The open-access MAF lists 12 somatic variants for this specimen: 7 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 3, Intron 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GATA2 | c.953C>T p.A318V | Missense Mutation (SNP) | VAF 41/91 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV62003120, COSV62003236, COSV62003503; called by muse, mutect2, varscan2
- EYS | c.3209A>T p.D1070V | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- HSPG2 | c.10669G>T p.A3557S | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- OTX1 | c.847C>A p.H283N | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0.018); called by muse, mutect2
- STING1 | c.994C>G p.H332D | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- TACC2 | c.848C>A p.P283Q | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.01); called by muse, mutect2
- TRAF7 | c.1556T>C p.L519P | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ADCY8 | c.2442C>T p.P814= | Silent (SNP) | VAF 23/56 reads (41%) | called by muse, mutect2, varscan2
- DCAF12L1 | c.357G>T p.T119= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as COSV100948153, COSV64421813; called by muse, mutect2
- SPTBN4 | c.2643C>T p.L881= | Silent (SNP) | VAF 28/80 reads (35%) | catalogued as rs1568795247, COSV58943447; called by muse, mutect2, varscan2
- CAPN1 | c.*33C>A | 3'UTR (SNP) | VAF 4/40 reads (10%) | called by muse, mutect2
- PTPN5 | c.1330-92C>T | Intron (SNP) | VAF 9/22 reads (41%) | catalogued as rs1564883967; called by muse, varscan2
